Somatic mutation profile of tumor specimen 0DMBM8 from CCDI case PBBZXG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.9 years (2,510 days).
Specimen 0DMBM8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4ad1ebb4-0993-4025-a785-babc921d1dc2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DMBLF (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8b1e9e5a-f744-4445-bb4f-994e70936730

The open-access MAF lists 36 somatic variants for this specimen: 26 protein-altering or splice-affecting, 5 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 5, Intron 4, 5'UTR 1, Frame Shift Del 1, Splice Region 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 139/420 reads (33%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 198/441 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADGRG5 | c.1258G>A p.G420S | Missense Mutation (SNP) | VAF 83/575 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.072); catalogued as rs375753134; called by muse, mutect2, varscan2
- AKR1C4 | c.826C>T p.R276W | Missense Mutation (SNP) | VAF 396/1318 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.651); catalogued as rs529198618, COSV54125324; called by muse, mutect2, varscan2
- CTSV | c.742G>A p.V248I | Missense Mutation (SNP) | VAF 67/665 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.088); catalogued as rs560756442, COSV52344066; called by muse, mutect2, varscan2
- GTF3C1 | c.6275G>A p.R2092Q | Missense Mutation (SNP) | VAF 139/689 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs1034279593; called by muse, mutect2, varscan2
- ITPR3 | c.2758G>A p.V920M | Missense Mutation (SNP) | VAF 131/748 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.116); catalogued as rs779072484, COSV65405188; called by muse, mutect2, varscan2
- LENG8 | c.835C>T p.R279W | Missense Mutation (SNP) | VAF 197/661 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.727); catalogued as rs202195197, COSV100457998; called by muse, mutect2
- MX2 | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 90/547 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as rs983954578; called by muse, mutect2, varscan2
- OR6B2 | c.223T>A p.S75T | Missense Mutation (SNP) | VAF 90/1146 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.028); catalogued as rs1423767938; called by muse, mutect2
- TMC1 | c.1615A>G p.I539V | Missense Mutation (SNP) | VAF 135/475 reads (28%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.883); catalogued as rs1440539662; called by muse, mutect2, varscan2
- USP24 | c.2959C>T p.R987W | Missense Mutation (SNP) | VAF 58/561 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs772334656, COSV53760911; called by muse, mutect2, varscan2
- ZNF831 | c.1175C>T p.A392V | Missense Mutation (SNP) | VAF 103/699 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as rs756694854, COSV64037437; called by muse, mutect2, varscan2
- C10orf71 | c.3122C>A p.A1041E | Missense Mutation (SNP) | VAF 60/618 reads (10%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.771); called by muse, mutect2
- CDC14C | c.731A>T p.D244V (on ENST00000428251; = p.D137V on NM_152627.3) | Missense Mutation (SNP) | VAF 95/1391 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CRYBG1 | c.4532A>T p.E1511V | Missense Mutation (SNP) | VAF 122/696 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- DBN1 | c.1664C>G p.A555G | Missense Mutation (SNP) | VAF 38/568 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2
- DDHD1 | c.1409G>C p.R470T (on ENST00000323669; = p.R667T on NM_030637.3) | Missense Mutation (SNP) | VAF 147/523 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DSCAML1 | c.3461C>G p.P1154R (on ENST00000321322; = p.P1094R on NM_020693.4) | Missense Mutation (SNP) | VAF 156/1061 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IRAG2 | c.3638T>A p.M1213K (on ENST00000636465; = p.M258K on NM_006152.4 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 71/808 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- NEB | c.12998A>G p.H4333R | Missense Mutation (SNP) | VAF 92/855 reads (11%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- OAS3 | c.460+6G>T | Splice Region (SNP) | VAF 39/422 reads (9%) | called by muse, mutect2
- UMODL1 | c.3685A>T p.K1229* (on ENST00000408910 / NM_001004416.2; = p.K1357* on NM_173568.3) | Nonsense Mutation (SNP) | VAF 83/586 reads (14%) | called by muse, mutect2, varscan2
- VPS13D | c.9026G>A p.G3009D | Missense Mutation (SNP) | VAF 146/572 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- ZMIZ1 | c.884C>G p.A295G | Missense Mutation (SNP) | VAF 204/585 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.269); called by muse, mutect2, varscan2
- ZNF292 | c.5088_5091del p.Q1696Hfs*3 | Frame Shift Del (DEL) | VAF 92/523 reads (18%) | called by mutect2, pindel, varscan2
- A3GALT2 | c.858G>A p.A286= | Silent (SNP) | VAF 46/396 reads (12%) | catalogued as rs944098497, COSV57760344; called by muse, mutect2, varscan2
- AK7 | c.918A>G p.R306= | Silent (SNP) | VAF 208/446 reads (47%) | called by muse, mutect2, varscan2
- KIF17 | c.1851C>T p.A617= | Silent (SNP) | VAF 243/799 reads (30%) | catalogued as rs762833089; called by muse, mutect2, varscan2
- MYOM3 | c.1422G>C p.R474= | Silent (SNP) | VAF 107/733 reads (15%) | catalogued as rs1205013830; called by muse, mutect2, varscan2
- TRPM6 | c.3000G>A p.S1000= | Silent (SNP) | VAF 105/838 reads (13%) | catalogued as rs200855300; called by muse, mutect2, varscan2
- AQP3 | c.492+28C>T | Intron (SNP) | VAF 104/355 reads (29%) | catalogued as rs376690273; called by muse, mutect2, varscan2
- GPR87 | c.-29C>T | 5'UTR (SNP) | VAF 59/401 reads (15%) | called by muse, mutect2, varscan2
- PTPRG | c.190+49A>G | Intron (SNP) | VAF 37/221 reads (17%) | catalogued as rs775591460; called by muse, mutect2, varscan2
- REG3A | c.196-58C>T | Intron (SNP) | VAF 34/340 reads (10%) | called by muse, mutect2, varscan2
- SDHA | c.1064+53G>A | Intron (SNP) | VAF 30/325 reads (9%) | called by muse, mutect2, varscan2
